Surgical pathology report (de-identified scan), TCGA case TCGA-24-1555, project TCGA-OV (Ovarian Serous Cystadenocarcinoma), tissue source site Washington University, specimen TCGA-24-1555-01A (Primary Tumor).

[page 1 of 3]
SURGICAL PATHOLOGY REPORT

FINAL

24-1555

*** Converted Case * This report may not match the original report format**

DIAGNOSIS:

OVARIES, RIGHT & LEFT, BILATERAL SALPINGO-OOPHORECTOMY
- PAPILLARY SEROUS ADENOCARCINOMA,
POORLY DIFFERENTIATED

FALLOPIAN TUBES, RIGHT & LEFT, BILATERAL SALPINGO-OOPHORECTOMY
- PAPILLARY SEROUS ADENOCARCINOMA,
SEROSAL METASTASES

UTERUS, SEROSA, ABDOMINAL HYSTERECTOMY
- PAPILLARY SEROUS ADENOCARCINOMA, METASTATIC

OMENTUM, EXCISION - PAPILLARY SEROUS ADENOCARCINOMA, METASTATIC

APPENDIX, EXCISION - PAPILLARY SEROUS ADENOCARCINOMA, METASTATIC

UTERUS, CERVIX, ABDOMINAL HYSTERECTOMY
- NO HISTOPATHOLOGIC ABNORMALITY

UTERUS, ENDOMETRIUM, ABDOMINAL HYSTERECTOMY
- COMPLEX ATYPICAL HYPERPLASIA
WITH METAPLASIA

UTERUS, MYOMETRIUM, ABDOMINAL HYSTERECTOMY - LEIOMYOMAS

By this signature, I attest that the above diagnosis is based upon my personal examination of the slides (and/or other material indicated in the diagnosis).

***Report Electronically Reviewed and Signed Out By Conversion

Microscopic Description and Comment:

Both right and left ovaries are largely replaced by poorly differentiated papillary serous adenocarcinoma. There are areas of typical papillary growth and epithelial tufting, although significant areas of solid growth are also present. Tumor involves the surfaces of both ovaries, the serosal surfaces of the right and left fallopian tubes and uterus, the paratubal soft tissue, and the periappendiceal soft tissue. The omentum is extensively replaced by tumor. There are no significant histopathologic abnormalities in the cervix. The endometrium show

[page 2 of 3]
SURGICAL PATHOLOGY REPORT

local complex hyperplasia with atypia, a process associated with extensive squamous metaplasia. There is also focal marked cystic change in the endometrium. Leiomyomas are present in the myometrium.

SYNOPTIC REPORTING FORM FOR MALIGNANT OVARIAN NEOPLASMS

1. A neoplasm is PRESENT.
2. The HISTOLOGIC DIAGNOSIS is:
Serous adenocarcinoma
3. The LOCATION(S) OF THE PRIMARY TUMOR(S) is/are:
Right and left ovary (synchronous primary tumors)
4. The FIGO GRADE of the tumor is:
III (Tumor composed of greater than 50% solid cellular nests)
5. The NUCLEAR (BRODERS') GRADE of the tumor is:
G2 (Moderately-differentiated)
6. Tumor IS identified on the ovarian surface(s).
8. Tumor is metastatic to the surface of the adjacent fallopian tube.
9. Tumor invasion of the pelvic soft tissue CANNOT BE EVALUATED.
10. Tumor involvement of the pelvic peritoneum CANNOT BE EVALUATED.
11. Metastatic involvement of the EXTRAPELVIC peritoneum CANNOT BE EVALUATED.
12. Metastatic involvement of the omentum is PRESENT.
14. Metastatic involvement of the uterine serosa is PRESENT.
15. Metastatic involvement of the endometrium is ABSENT.
16. Regional lymph node metastases CANNOT BE EVALUATED.
19. DETAILED STAGING INFORMATION:
Based on the above information, the PRIMARY TUMOR is classified as:

TNM SCHEME	FIGO SCHEME	DEFINITION
T3c	IIIC	Macroscopic peritoneal metastasis beyond true pelvis measuring greater than 2 cm in greatest dimension, OR Regional lymph node metastasis OR Metastasis to capsule of liver.

THE REGIONAL LYMPH NODES are classified as:

NX (Nodal status cannot be assessed)

THE STATUS OF DISTANT TUMOR SITES is classified as:

MX (Status cannot be assessed)

20. The FINAL AJCC/FIGO STAGE IS:

AJCC SCHEME	FIGO SCHEME
X	Insufficient data to assign stage

The pathologic stage assigned here should be regarded as provisional, and may change after integration of clinical data not provided with this specimen.

History:

The patient with a pelvic mass, ascites, and an elevated CA125. Operative procedure: Total abdominal hysterectomy, bilateral salpingo-oophorectomy, appendectomy and omental biopsy.

An intraoperative non-microscopic consultation was obtained and interpreted as: 11.0 X 6.0 X 5.0 cm uterus and cervix with attached right and left tubes and ovaries. The right and left ovaries are both enlarged. The interior of the ovaries are multinodular and papillary with small serous cysts. Portions of the right ovary and posterior cervix are donated for research. Tumor metastases are present on bowel and in pelvic peritoneum," by

Specimen(s) Received:

A: UTERUS, CERVIX, BIL TUBES AND OVARIES
B: APPENDIX
C: OMENTUM

[page 3 of 3]
Gross Description:

The specimens are received in three containers of formalin, each labelled with the patient's name. The first container is labeled "uterus, cervix and bilateral tubes and ovaries." It consists of the uterine cervix, uterine fundus and bilateral adnexal structures. The entire specimen weighs 256.0 grams. The uterus measures 11.0 cm in length, 6.0 cm from cornu-to-cornu, 5.0 cm from anterior to posterior. The ectocervix is circular, tan-white with focal areas of hemorrhage and measures 3.0 cm in diameter. The external os is circular and measures 0.2 cm in diameter. The specimen is bivalved. The endocervix is tan-brown with a polyp that measures 0.7 cm in greatest dimension present in the anterior portion. The endocervical canal measures 3.5 cm in length. The endometrial cavity measures 4.5 cm in length and 2.5 cm in width. The endometrium is tan-brown with focal areas of hemorrhage and measures 0.1 cm in thickness. A tan-brown polyp that measures 1.0 cm in greatest dimension is present in the lower uterine segment in the anterior endometrium. The myometrium is tan-brown and measures 2.0 cm in greatest thickness. Sections show multiple intramural leiomyomas that measure from 0.5 to 1.2 cm. in greatest dimension. The serosal surface is tan-brown with numerous tan-white nodules that measure from 0.2 to 1.5 cm in greatest dimension. The right fallopian tube is tan-brown and is adherent to the right ovary. It measures 5.5 cm in length and 0.5 cm in diameter. The fimbriae are normal. Sections show unremarkable tan-brown parenchyma. The right ovary is tan-brown and lobulated. It measures 5.0 x 3.5 x 3.2 cm. Sections show multiple cysts with tan-brown papillary excrescences that fill the cyst cavities. The walls measure 0.1 cm in greatest thickness. The cavities measure from 2.0 to 2.5 cm in greatest dimension. The tumor is grossly confined to the ovary. The left fallopian tube is tan-brown and adherent to the left ovary. It measures 6.0 cm in length and 0.7 cm in diameter. The fimbriae are normal. Sections show unremarkable tan-brown tissue. The left ovary is tan-brown with lobulation and measures 4.5 x 3.7 x 3.4 cm. Sections show multiple cysts filled with tan-brown, solid tissue. The cysts measure from 1.0 to 2.0 cm in greatest dimension. The tumor is grossly confined to the ovary. Labeled C1 - anterior cervix; EC1 - anterior lower uterine segment; E1 - anterior endometrium; C2 - posterior cervix; EC2 - posterior lower uterine segment; E2 - posterior endometrium; AS1 - anterior serosa; PS1 - posterior serosa; LT - left fallopian tube; LO1 through LO4 - left ovary; - right fallopian tube; RO1 through RO4 - right ovary; additional endometrium E3 through E5.

The second container is labeled "appendix." It contains an appendix that measures 5.5 cm in length and 1.5 cm in diameter. The outer surface is studded with numerous adhesions and tan-white nodules that measure from 0.2 to 0.3 cm in greatest dimension. Mesenteric fat runs the entire length of the specimen and measures 0.5 cm in thickness. Sections show the wall measures 0.2 cm in thickness. No mucosal lesions are seen. The tip is grossly distorted. Labeled A.

The third container is labeled "omentum," and contains multiple fragments of tan-yellow, fibrotic fat that measures 14.0 x 9.5 x 6.0 cm in aggregate. Sections show diffuse involvement by tumor throughout the omentum.

Source: NCI Genomic Data Commons file 7e8bbfae-1321-4d17-96d1-3de142a8eb9b (TCGA-24-1555.B7B2F370-207A-4849-B7A0-528789363A02.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).